Somatic mutation profile of tumor specimen TCGA-A7-A4SE-01A (aliquot TCGA-A7-A4SE-01A-11D-A25Q-09) from TCGA case TCGA-A7-A4SE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.0 years (20,080 days).
Specimen TCGA-A7-A4SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c4d903-d5e8-42bb-8677-898ee041a188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A4SE-10A (Blood Derived Normal), aliquot TCGA-A7-A4SE-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56f376c8-0773-41a1-9f41-82dcd379819d

The open-access MAF lists 96 somatic variants for this specimen: 78 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 16, Frame Shift Del 8, Nonsense Mutation 3, Splice Site 3, Splice Region 1, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 28/42 reads (67%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB10 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV60620756; called by muse, mutect2, varscan2
- ABCD3 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100931446; called by muse, mutect2
- ACTR1B | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as COSV56703927; called by muse, mutect2, varscan2
- ADGRE2 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as COSV59692938; called by muse, mutect2, varscan2
- ADGRE5 | c.741C>G p.I247M (on ENST00000242786 / NM_078481.4; = p.I154M on NM_001784.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV54409835; called by muse, varscan2
- AGBL1 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV69797347; called by muse, mutect2, varscan2
- ALPK3 | c.3831C>G p.I1277M | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51932466; called by muse, mutect2, varscan2
- APOA1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs750125257, COSV52635605; ClinVar: benign; called by muse, mutect2, varscan2
- ARHGAP5 | c.1757T>A p.L586* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61535047; called by muse, mutect2, varscan2
- ARHGAP5 | c.2290G>C p.V764L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV61535052; called by muse, mutect2, varscan2
- ATP11C | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV59559340; called by muse, mutect2
- BLM | c.3323G>C p.R1108T | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100757309, COSV61923505; called by muse, mutect2
- BPTF | c.4599A>G p.I1533M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.021); catalogued as COSV58835711; called by muse, mutect2, varscan2
- CEP152 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV100359075; called by muse, mutect2
- CLDN18 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.198); catalogued as COSV59302428, COSV59302939; called by muse, mutect2, varscan2
- COL3A1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58582150; called by muse, mutect2, varscan2
- COL3A1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1325737333, COSV58584908; called by muse, mutect2, varscan2
- CPS1 | c.2680C>G p.L894V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV51807808; called by muse, mutect2, varscan2
- DGKH | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs747484150, COSV54930744; called by muse, mutect2, varscan2
- DIPK1B | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 119/193 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV63037973; called by muse, mutect2, varscan2
- DYTN | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65970622; called by muse, mutect2, varscan2
- EIF2S2 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66621371, COSV66621396; called by muse, mutect2, varscan2
- ELL | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.517); catalogued as rs538570775, COSV53212173; called by muse, mutect2, varscan2
- ENC1 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV56629353; called by muse, mutect2, varscan2
- ETV1 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54139681, COSV54140895; called by muse, mutect2, varscan2
- FLG2 | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV66167995; called by muse, mutect2, varscan2
- ITIH1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV56258472, COSV99835578; called by muse, mutect2
- KCNH2 | c.2894G>C p.G965A | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100060876; called by muse, mutect2
- KYAT3 | c.668T>A p.V223E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53100366; called by muse, mutect2, varscan2
- LEMD2 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53393686; called by muse, mutect2, varscan2
- LNX1 | c.1958T>C p.I653T (on ENST00000263925 / NM_001126328.3; = p.I557T on NM_032622.2) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759216838, COSV55784431; called by muse, mutect2, varscan2
- LRP1B | c.6778G>A p.D2260N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs142974716; called by muse, mutect2, varscan2
- MAT1A | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64745309; called by muse, mutect2, varscan2
- MGAM | c.2288G>A p.G763D | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV72074469; called by muse, mutect2, varscan2
- MIPEP | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV66300316; called by muse, mutect2, varscan2
- NDUFA1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65097267; called by muse, mutect2, varscan2
- NT5DC3 | c.1394+1G>C p.X465_splice | Splice Site (SNP) | VAF 45/83 reads (54%) | catalogued as COSV67321612; called by muse, mutect2, varscan2
- OR11G2 | c.435G>C p.L145F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV62132124; called by muse, mutect2, varscan2
- PHF1 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV65702671, COSV65702898; called by muse, mutect2, varscan2
- PMP2 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1563519267, COSV56266928; called by muse, mutect2, varscan2
- POLA1 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as COSV66885562; called by muse, mutect2, varscan2
- PRUNE1 | c.439T>G p.S147A | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54957904; called by muse, mutect2, varscan2
- PTCH1 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59470705; called by muse, mutect2, varscan2
- PUS7 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV100708625; called by muse, mutect2
- QRICH2 | c.4691A>G p.Y1564C | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53152565; called by muse, mutect2, varscan2
- RASGEF1C | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100746296, COSV63181805; called by muse, mutect2, varscan2
- RET | c.2887C>G p.L963V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60691858; called by muse, mutect2, varscan2
- RIC3 | c.544G>A p.D182N (on ENST00000309737 / NM_001206671.4; = p.D181N on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV58301664; called by muse, mutect2, varscan2
- ROBO3 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV67300316; called by muse, mutect2, varscan2
- RORC | c.1396C>T p.L466= | Splice Region (SNP) | VAF 6/116 reads (5%) | catalogued as rs1309076817, COSV100562076; called by muse, mutect2
- RTN3 | c.1435G>C p.D479H (on ENST00000377819 / NM_001265589.2; = p.D460H on NM_201428.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV58028169; called by muse, mutect2
- SIRPA | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.368); catalogued as COSV61537949; called by muse, mutect2, varscan2
- SLC25A43 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54217527; called by muse, mutect2, varscan2
- SLC38A10 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55844695; called by muse, mutect2, varscan2
- SLC4A5 | c.2727G>C p.E909D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61026806; called by muse, mutect2, varscan2
- SPTA1 | c.6064G>A p.E2022K | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV63751832; called by muse, mutect2
- SSX5 | c.206C>G p.P69R (on ENST00000347757 / NM_175723.1; = p.P110R on NM_021015.4) | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100308874; called by muse, mutect2
- TANK | c.726C>G p.D242E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV52044502; called by muse, mutect2, varscan2
- TMEM140 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV51966014; called by muse, mutect2, varscan2
- TONSL | c.1689G>C p.W563C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340302; called by muse, mutect2, varscan2
- UBE3A | c.2381T>A p.V794D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51663914; called by muse, mutect2, varscan2
- XRN1 | c.2813G>C p.G938A | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV53810511; called by muse, mutect2, varscan2
- ZBED8 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV68824639; called by muse, mutect2, varscan2
- ZFPM2 | c.2866G>T p.E956* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV65873139, COSV65873794; called by muse, mutect2, varscan2
- ZNF17 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568539302, COSV56921202; called by muse, mutect2, varscan2
- ZNF462 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.028); catalogued as COSV52935705; called by muse, mutect2, varscan2
- ZNF582 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV56731851; called by muse, mutect2, varscan2
- CCDC81 | c.1656_1671del p.R552Sfs*20 (on ENST00000445632 / NM_001156474.2; = p.R462Sfs*20 on NM_021827.4) | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- DCUN1D4 | c.361_368del p.G121Rfs*7 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- DENND2B | c.1841_1845+32del p.X614_splice | Splice Site (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- EPS8L3 | c.1371_1381del p.L458* (on ENST00000361965 / NM_133181.4; = p.L428* on NM_024526.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- FLYWCH2 | c.366_406del p.E123Rfs*34 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel
- SHARPIN | c.576_601del p.Q193Sfs*25 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel
- SHISA4 | c.173_187del p.Y58_C62del | In Frame Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- SYNM | c.2208del p.R737Gfs*17 | Frame Shift Del (DEL) | VAF 34/55 reads (62%) | called by mutect2, pindel, varscan2
- TNFRSF10D | c.356_357del p.T119Sfs*3 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | called by mutect2, pindel, varscan2
- UBE2G1 | c.260_267del p.G87Vfs*7 | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | called by mutect2, pindel, varscan2
- ALDH8A1 | c.117G>A p.V39= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV55641228; called by muse, mutect2, varscan2
- BOD1L1 | c.2997G>A p.E999= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs777570487, COSV50009880; called by muse, mutect2, varscan2
- CLDN18 | c.165A>T p.R55= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV59301439, COSV59302439; called by muse, mutect2, varscan2
- DSP | c.6373C>T p.L2125= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1246415961, COSV65792334; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF3 | c.987T>C p.C329= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV61712218; called by muse, mutect2, varscan2
- KANK2 | c.1347C>A p.T449= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as COSV62007544; called by muse, mutect2, varscan2
- LGALS12 | c.564G>T p.V188= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55369940; called by muse, mutect2, varscan2
- LRRC1 | c.1155G>A p.L385= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV63828807; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.256C>T p.L86= (on ENST00000259318 / NM_001136562.3; = p.L317= on NM_007203.5) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1196161585, COSV52175403; called by muse, mutect2, varscan2
- PKHD1 | c.6462T>A p.V2154= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV61870972; called by muse, mutect2, varscan2
- PLXDC2 | c.1404C>T p.A468= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs752060811, COSV65902988; called by muse, mutect2, varscan2
- RECQL4 | c.2841G>C p.L947= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV56740605; called by muse, mutect2, varscan2
- SFPQ | c.84C>A p.L28= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV61758519; called by muse, mutect2, varscan2
- SH3TC2 | c.594G>A p.L198= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV60462546; called by muse, mutect2, varscan2
- SLC4A8 | c.2790C>G p.L930= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV60650900; called by muse, mutect2, varscan2
- TYRP1 | c.1308A>G p.R436= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV66357869; called by muse, mutect2, varscan2
- ABCA3 | c.-150G>T | 5'UTR (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100069028; called by muse, mutect2, varscan2
- ZNF99 | c.4-639A>T | Intron (SNP) | VAF 22/57 reads (39%) | catalogued as COSV68055484; called by muse, mutect2, varscan2
